Somatic mutation profile of tumor specimen BA2758D (aliquot aq-BA2758D) from BEATAML1.0 case 2453, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.4 years (27,908 days).
Specimen BA2758D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c369e3e3-654e-4595-9d79-b816e40930e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2205D (Solid Tissue Normal), aliquot aq-BA2205D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e8d9662-8348-4c4e-8c1c-adf41288c652

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AS3MT | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); catalogued as rs1564789532, COSV54915979; called by muse, mutect2, varscan2
- IKBKG | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as CD141303; called by muse, mutect2, varscan2
- SF3B1 | c.1986C>G p.H662Q | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778467242, COSV59205547, COSV59208501; called by muse, mutect2, varscan2
- SPTBN5 | c.1962G>C p.W654C | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV100311958; called by muse, mutect2, varscan2
- SUSD5 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); catalogued as rs372702857; called by muse, mutect2, varscan2
- WDR86 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1340952111; called by muse, mutect2
- ZRSR2 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs1317146058, COSV57066880; called by muse, mutect2
- ANKRD62 | c.2728C>T p.L910F | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT39 | c.462G>T p.Q154H | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAD54L2 | c.3473C>A p.A1158D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.007); called by muse, mutect2
- RIMBP3 | c.2615A>T p.D872V | Missense Mutation (SNP) | VAF 37/412 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- RUNX1 | c.931del p.A311Rfs*256 (on ENST00000344691 / NM_001001890.3; = p.A338Rfs*256 on NM_001754.5) | Frame Shift Del (DEL) | VAF 23/41 reads (56%) | called by mutect2, pindel, varscan2
- SPTBN5 | c.2057C>G p.A686G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ACACB | c.5778C>A p.V1926= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- SLC2A7 | c.1356C>T p.A452= | Silent (SNP) | VAF 8/186 reads (4%) | catalogued as rs958262997; called by muse, mutect2
